Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3D5, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3D5-01A (Primary Tumor).

[page 1 of 2]
Duration/Synchronous Primary Noted		☒
10/15/11		

DOB:
Physician:

Sex: F

Collected

Accession

Received

Case type: Surgical Case

DIAGNOSIS

(A) SCAR:

Skin with scar, negative for tumor.

(B) RIGHT NECK DISSECTION, LEVEL II:

METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF NINE LYMPH NODES (1/9).
Extranodal extension is not identified.

(C) RIGHT NECK DISSECTION, LEVEL III:

METASTATIC PAPILLARY THYROID CARCINOMA IN FOUR OF SEVEN LYMPH NODES (4/7).
Extranodal extension is not identified.

(D) RIGHT NECK DISSECTION, LEVEL IV:

METASTATIC PAPILLARY THYROID CARCINOMA IN SEVEN OF SEVEN LYMPH NODES (7/7).
Extranodal extension is not identified.

(E) RIGHT INFERIOR PARATHYROID:

Hyperplastic parathyroid tissue, no tumor present.

(F) TOTAL THYROIDECTOMY:

PAPILLARY THYROID CARCINOMA, WITH ONCOCYTIC AND FOLLICULAR COMPONENTS

Location: Bilateral

Multi-focal: Yes

Size = 2.5 cm, Largest focus, right lobe

Extrathyroidal extension: Present, extending into fibroadipose tissue

Lymphovascular invasion: Present

Resection Margins: Negative

Background Thyroid: Multinodular adenomatous goiter

Lymph nodes: No tumor present in 1 lymph node

Thyroglossal duct remnant associated with isthmus (F8)

ICD-0-3

carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS C73.9

10/15/11

(G) PARATRACHEAL DISSECTION, RIGHT:

METASTATIC PAPILLARY THYROID CARCINOMA IN THREE OF SEVEN LYMPH NODES (3/7).
Extranodal extension is not identified.

GROSS DESCRIPTION

(A) SCAR - Received is a ribbon of tan-pink, unremarkable skin. Section reveals a fibrotic cut surface. Representative sections are submitted in A.

[page 2 of 2]
Surgical Pathology Report

DOB:
Physician:

Sex: F

Collected:

Pathologist:

Accession:

Received

Case type: Surgical Case

(B) RIGHT NECK DISSECTION LEVEL II - Two yellow-tan portions of adipose tissue (2.2 x 1.5 x 1 cm and 6.2 x 3 x 1 cm). Nine potential lymph nodes are palpated, ranging in size from 0.3 - 1.2 cm in greatest dimension. No gross tumor.

SECTION CODE: B1, five potential lymph nodes; B2, three potential lymph nodes; B3, single largest lymph node, sectioned; B4, representative adipose tissue.

(C) RIGHT NECK DISSECTION LEVEL III - One piece of adipose tissue (6.5 x 4.5 x 0.7 cm). Eight potential lymph nodes are palpated, ranging in size from 0.2 - 1.5 cm in greatest dimension.

SECTION CODE: C1, five potential lymph nodes; C2-C4, single potential lymph node in each.

(D) RIGHT NECK DISSECTION LEVEL IV - yellow-tan adipose tissue (3.5 x 3 x 1 cm). Eight potential lymph nodes are palpated, ranging in size from 0.5 - 1.6 cm in greatest dimensions. The largest lymph node has a cystic cut surface, possibility representing metastatic disease. No tumor is evident beyond the capsule of the lymph node.

SECTION CODE: D1, three potential lymph nodes; D2, four potential lymph nodes; D3, D4, single largest lymph node, serially sectioned.

(E) RIGHT INFERIOR PARATHYROID - A 0.2 x 0.2 x 0.2 cm soft tissue fragment, entirely submitted for frozen in E.
*FS/DX: PARATHYROID TISSUE.

(F) TOTAL THYROIDECTOMY, STITCH RIGHT UPPER LOBE - a total thyroidectomy specimen including right thyroid lobe (6 x 4 x 2 cm), isthmus (2 x 2 x 0.7 cm) and left thyroid lobe (3 x 2 x 2 cm). In the right thyroid lobe, there are two firm nodules: The lower nodule (2.5 x 1.5 x 1 cm) with a cavity filled with hemorrhagic material and an upper nodule (2.2 x 1.5 x 1 cm). The two nodules are next to each other. In the left thyroid lobe, one well-circumscribed, tan-brown nodule is present (0.5 x 0.5 x 0.4 cm). The capsule is intact, smooth, otherwise unremarkable.

SECTION CODE: F1, right lower nodule with a central cavity; F2, F3, contains both nodules showing their relationship; F4, F5, upper nodules; F6, F7, representative sectioning of right lobe; F8, F9, representative sectioning of isthmus; F10, F11, left thyroid nodule; F12-F14, representative sectioning of left thyroid lobe. QS/msm

(G) PARATRACHEAL DISSECTION, RIGHT - pink-red soft tissue (6 x 1 x 0.5 cm). Multiple lymph nodes are identified from the specimen, range from 0.3 - 1.5 cm in greatest dimension.

SECTION CODE: G1, five possible lymph nodes; G2, four possible lymph nodes; G3, one lymph node, bisected; G4, one lymph node, serially sectioned.

CLINICAL HISTORY

Papillary thyroid carcinoma

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by I
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by: I

Surgical Pathology Report	Page 2 of 2
File under: Pathology	

Source: NCI Genomic Data Commons file 13ac6646-3318-4094-844f-b25d5f845289 (TCGA-EL-A3D5.D52D36F3-9D5A-4176-8146-76A6AA4B8148.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).